CPTAC case C3L-00401 — Pancreas — Ductal and Lobular Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b8bda40b-9820-47a9-abb4-4ebcb2cf8b62

Demographics
Sex at birth: female; Year of birth: 1953; Vital status: Dead; Days to death: 1,262 days (3.5 years); Year of death: 2020; Cause of death: Cancer Related; Country of birth: Canada.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Body of pancreas; Age at diagnosis: 62.9 years (22,991 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 1,262 days (3.5 years); Progression or recurrence: yes; Days to last follow up: 1,262 days (3.5 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.8 cm (a second GDC size field records 0.9 cm); Lymph node involvement: Positive; Lymph nodes positive: 3; Lymph nodes tested: 40; Lymphatic invasion present: Yes; Margin status: Uninvolved; Perineural invasion present: Yes; Vascular invasion present: Yes.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (4 entries)
- Days to follow up: 353 days; Disease response: Complete Response; Karnofsky performance status: 90; ECOG performance status: 0.
- Days to follow up: 696 days (1.9 years); Disease response: Progressive Disease; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,228 days (3.4 years); Disease response: Progressive Disease; Karnofsky performance status: 60; ECOG performance status: 2.
- Days to follow up: 1,262 days (3.5 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 532 days (1.5 years); Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 60.3 kg; Height: 164 cm; BMI: 22.42.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (5 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-00401-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -8 days; Initial weight: 67 mg; Time between excision and freezing: 35 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00401-22: Section location: Body; Percent tumor nuclei: 40; Percent necrosis: 0.
- Sample C3L-00401-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -8 days; Initial weight: 67 mg; Time between excision and freezing: 35 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00401-24: Section location: Body; Percent tumor nuclei: 15; Percent necrosis: 2.
- Sample C3L-00401-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -8 days; Initial weight: 67 mg; Time between excision and freezing: 35 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-00401-25: Section location: Body; Percent tumor nuclei: 25; Percent necrosis: 2.
- Sample C3L-00401-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -8 days; Method of sample procurement: Blood Draw.
- Sample C3L-00401-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
